Somatic mutation profile of tumor specimen CPT000816 (aliquot CPT000816-0010) from CPTAC case 100002921, project CPTAC-2 (Breast). Sex at birth: female; Tissue or organ of origin: Breast, NOS; Age at diagnosis: 59.0 years (21,534 days).
Specimen CPT000816: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 269979ff-bc1c-48dc-bcb9-fcdf3f4ddd1e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen CPT000822 (Blood Derived Normal), aliquot CPT000822-0002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d62c31b0-6c94-49ef-acb2-38af3cb452a4

The open-access MAF lists 227 somatic variants for this specimen: 162 protein-altering or splice-affecting, 44 silent, 21 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 123, Silent 44, Frame Shift Del 13, Intron 11, Nonsense Mutation 9, Splice Site 8, RNA 5, In Frame Del 4, 5'UTR 3, Frame Shift Ins 3, Splice Region 2, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA4 | c.1372C>A p.P458T | Missense Mutation (SNP) | VAF 61/107 reads (57%) | SIFT deleterious (0.01); PolyPhen benign (0.094); catalogued as COSV64676792; called by muse, mutect2, varscan2
- ABCA6 | c.3085C>G p.P1029A | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); catalogued as COSV52637747, COSV52643669; called by muse, mutect2, varscan2
- AC139530.2 | c.186dup p.K63Qfs*118 | Frame Shift Ins (INS) | VAF 104/214 reads (49%) | catalogued as rs769882870; called by mutect2, varscan2
- ACSM5 | c.1206+2T>C p.X402_splice | Splice Site (SNP) | VAF 77/198 reads (39%) | catalogued as COSV59374074; called by muse, mutect2, varscan2
- ADAMTS19 | c.1153C>G p.L385V | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT tolerated (0.18); PolyPhen benign (0.028); catalogued as COSV50785531; called by muse, mutect2, varscan2
- ADSL | c.335C>A p.S112Y | Missense Mutation (SNP) | VAF 42/139 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53409615; called by muse, mutect2, varscan2
- AGL | c.526G>C p.A176P | Missense Mutation (SNP) | VAF 52/114 reads (46%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.922); catalogued as COSV54057180; called by muse, mutect2, varscan2
- AHCTF1 | c.1040A>T p.K347M (on ENST00000366508; = p.K321M on NM_015446.5) | Missense Mutation (SNP) | VAF 9/96 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV58254025; called by muse, mutect2
- AKAP6 | c.6141T>A p.H2047Q | Missense Mutation (SNP) | VAF 54/148 reads (36%) | SIFT tolerated (0.22); PolyPhen benign (0.139); catalogued as rs1226703932, COSV55228820; called by muse, mutect2, varscan2
- ANKRD36C | c.3433G>A p.A1145T | Missense Mutation (SNP) | VAF 39/137 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.983); catalogued as COSV54765429; called by muse, mutect2, varscan2
- ANKRD50 | c.251C>G p.T84R | Missense Mutation (SNP) | VAF 109/332 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV72386167; called by muse, mutect2, varscan2
- ARHGAP24 | c.392-1G>T p.X131_splice (on ENST00000395184 / NM_001025616.3; = p.X38_splice on NM_031305.3) | Splice Site (SNP) | VAF 38/116 reads (33%) | catalogued as COSV51992685; called by mutect2, varscan2
- ARMC8 | c.1279G>C p.V427L (on ENST00000469044 / NM_001363941.2; = p.V413L on NM_015396.6) | Missense Mutation (SNP) | VAF 112/227 reads (49%) | SIFT tolerated (0.05); PolyPhen benign (0.024); catalogued as COSV58617422, COSV58621917; called by muse, mutect2, varscan2
- ARRDC3 | c.613+1G>A p.X205_splice | Splice Site (SNP) | VAF 13/21 reads (62%) | catalogued as COSV99475305; called by muse, mutect2, varscan2
- ASPH | c.458C>G p.S153C | Missense Mutation (SNP) | VAF 23/85 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.907); catalogued as COSV62860948; called by muse, mutect2, varscan2
- BRCA2 | c.8777T>G p.L2926* | Nonsense Mutation (SNP) | VAF 48/125 reads (38%) | catalogued as COSV66460540; called by muse, mutect2, varscan2
- C1QTNF2 | c.369C>A p.S123R (on ENST00000393975; = p.S78R on NM_031908.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 66/189 reads (35%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as rs543986035; called by muse, mutect2, varscan2
- CASR | c.1031A>T p.H344L | Missense Mutation (SNP) | VAF 94/277 reads (34%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as CX104669, COSV56140637; called by muse, mutect2, varscan2
- CC2D2A | c.1975A>T p.S659C | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.698); catalogued as COSV101052791; called by muse, mutect2
- CCDC120 | c.1885T>C p.F629L | Missense Mutation (SNP) | VAF 69/194 reads (36%) | SIFT tolerated, low confidence (0.15); PolyPhen possibly damaging (0.827); catalogued as COSV100896685; called by muse, mutect2, varscan2
- CCDC185 | c.1122C>G p.C374W | Missense Mutation (SNP) | VAF 51/264 reads (19%) | SIFT deleterious (0.05); PolyPhen benign (0.052); catalogued as COSV64821660; called by muse, mutect2, varscan2
- CDR1 | c.359A>C p.D120A | Missense Mutation (SNP) | VAF 20/82 reads (24%) | SIFT deleterious (0.05); PolyPhen benign (0.224); catalogued as COSV65164649; called by muse, mutect2, varscan2
- CELSR2 | c.8248G>A p.E2750K | Missense Mutation (SNP) | VAF 73/233 reads (31%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0); catalogued as COSV104375627, COSV54778007; called by muse, mutect2, varscan2
- CFAP47 | c.1747A>G p.M583V | Missense Mutation (SNP) | VAF 30/106 reads (28%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as COSV52890251; called by muse, varscan2
- CLSTN2 | c.566C>A p.S189Y | Missense Mutation (SNP) | VAF 102/446 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV71720174, COSV71724134; called by mutect2, varscan2
- COL4A4 | c.4127C>G p.P1376R | Missense Mutation (SNP) | VAF 68/210 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.831); catalogued as COSV61635599; called by muse, mutect2, varscan2
- COL6A6 | c.852C>A p.S284R | Missense Mutation (SNP) | VAF 70/263 reads (27%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.739); catalogued as COSV62028817, COSV62034537; called by mutect2, varscan2
- CSMD2 | c.2428G>A p.D810N | Missense Mutation (SNP) | VAF 42/131 reads (32%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.993); catalogued as rs1400205787, COSV53911075, COSV53950617; called by muse, mutect2, varscan2
- CYP4F11 | c.718C>G p.L240V | Missense Mutation (SNP) | VAF 70/261 reads (27%) | SIFT tolerated (0.41); PolyPhen benign (0.291); catalogued as COSV56129045; called by muse, mutect2, varscan2
- DDX60L | c.4924A>T p.N1642Y | Missense Mutation (SNP) | VAF 22/102 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV99487699; called by mutect2, varscan2
- DNAH5 | c.5569C>T p.Q1857* | Nonsense Mutation (SNP) | VAF 54/144 reads (38%) | catalogued as COSV54246275; called by muse, mutect2, varscan2
- DNALI1 | c.824T>C p.I275T (on ENST00000296218; = p.I253T on NM_003462.5) | Missense Mutation (SNP) | VAF 32/106 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.667); catalogued as COSV56171202; called by muse, mutect2, varscan2
- DOCK2 | c.5239G>T p.V1747F | Missense Mutation (SNP) | VAF 120/320 reads (38%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.034); catalogued as COSV56981491; called by muse, varscan2
- DOCK5 | c.2193G>A p.V731= | Splice Region (SNP) | VAF 34/52 reads (65%) | catalogued as COSV52409101; called by muse, mutect2, varscan2
- EPHA10 | c.1528G>T p.G510W | Missense Mutation (SNP) | VAF 40/124 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100361431, COSV57623350; called by mutect2, varscan2
- EPN3 | c.113C>T p.S38L | Missense Mutation (SNP) | VAF 69/277 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1365357138, COSV52139596; called by muse, mutect2, varscan2
- ETV6 | c.1133G>C p.R378P | Missense Mutation (SNP) | VAF 39/77 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs146280653; called by muse, mutect2, varscan2
- FMN2 | c.4887T>G p.N1629K | Missense Mutation (SNP) | VAF 18/91 reads (20%) | SIFT tolerated (0.9); PolyPhen benign (0.023); catalogued as rs1195070581, COSV60441719; called by muse, mutect2, varscan2
- GPR108 | c.1363G>A p.V455I (on ENST00000264080 / NM_001080452.1; = p.V213I on NM_020171.2) | Missense Mutation (SNP) | VAF 58/144 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs757468810, COSV51186763; called by muse, mutect2, varscan2
- GPR37 | c.1100A>C p.Q367P | Missense Mutation (SNP) | VAF 138/245 reads (56%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.953); catalogued as COSV58259138; called by muse, mutect2, varscan2
- GRIA1 | c.1968G>C p.Q656H | Missense Mutation (SNP) | VAF 64/265 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53619895; called by muse, mutect2, varscan2
- HEATR1 | c.3000G>C p.L1000F | Missense Mutation (SNP) | VAF 19/117 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.945); catalogued as COSV63982688; called by muse, mutect2, varscan2
- HERC5 | c.1034C>A p.S345* | Nonsense Mutation (SNP) | VAF 18/65 reads (28%) | catalogued as COSV52040319, COSV52040466; called by muse, mutect2, varscan2
- HSD17B4 | c.736C>G p.L246V (on ENST00000414835 / NM_001199291.3; = p.L221V on NM_000414.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 39/68 reads (57%) | SIFT tolerated (0.36); PolyPhen benign (0.166); catalogued as COSV56338516, COSV99820079; called by muse, mutect2, varscan2
- ITIH1 | c.1705C>G p.L569V | Missense Mutation (SNP) | VAF 86/212 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs970449516, COSV56257854; called by muse, mutect2, varscan2
- KAT2A | c.2022C>T p.I674= | Splice Region (SNP) | VAF 78/199 reads (39%) | catalogued as COSV52427795; called by muse, mutect2, varscan2
- KIAA0825 | c.2604C>G p.N868K | Missense Mutation (SNP) | VAF 50/89 reads (56%) | SIFT tolerated (0.95); PolyPhen benign (0.357); catalogued as COSV56958333; called by muse, mutect2, varscan2
- KIAA1841 | c.1823A>G p.K608R | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.039); catalogued as COSV54378010; called by muse, mutect2, varscan2
- KRT73 | c.1408G>A p.A470T | Missense Mutation (SNP) | VAF 78/250 reads (31%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as rs956494844, COSV59839214; called by muse, mutect2, varscan2
- LETM1 | c.721G>A p.E241K | Missense Mutation (SNP) | VAF 39/110 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.327); catalogued as COSV57103723; called by muse, mutect2, varscan2
- LMOD1 | c.875A>G p.E292G | Missense Mutation (SNP) | VAF 84/412 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0.006); catalogued as rs748818678, COSV66173674; called by muse, mutect2, varscan2
- LRRC70 | c.601C>T p.Q201* | Nonsense Mutation (SNP) | VAF 69/138 reads (50%) | catalogued as COSV57580650; called by muse, mutect2, varscan2
- METTL11B | c.289G>T p.D97Y | Missense Mutation (SNP) | VAF 22/103 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63030202; called by muse, mutect2, varscan2
- MROH7 | c.3873C>A p.H1291Q | Missense Mutation (SNP) | VAF 177/512 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV64888111; called by muse, mutect2, varscan2
- MSH5 | c.2181+1G>C p.X727_splice | Splice Site (SNP) | VAF 71/266 reads (27%) | catalogued as rs376571710, COSV100991808, COSV100991859; called by muse, mutect2, varscan2
- MUC16 | c.5272C>A p.P1758T | Missense Mutation (SNP) | VAF 220/560 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.139); catalogued as COSV101198414, COSV67486758; called by muse, mutect2, varscan2
- MYH11 | c.2950G>C p.E984Q | Missense Mutation (SNP) | VAF 123/372 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.725); catalogued as COSV55565683; called by muse, mutect2, varscan2
- MYH11 | c.1631C>A p.A544D | Missense Mutation (SNP) | VAF 113/393 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55565704; called by muse, mutect2, varscan2
- MYO7B | c.2725G>A p.V909I | Missense Mutation (SNP) | VAF 91/191 reads (48%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as rs371739405; called by muse, mutect2, varscan2
- NBAS | c.5830G>A p.A1944T | Missense Mutation (SNP) | VAF 78/194 reads (40%) | SIFT tolerated (0.29); PolyPhen benign (0.001); catalogued as rs773223545, COSV55734366; called by muse, mutect2, varscan2
- NPAT | c.2836G>A p.V946I | Missense Mutation (SNP) | VAF 30/113 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV53720992; called by muse, mutect2, varscan2
- NUDT21 | c.311T>G p.F104C | Missense Mutation (SNP) | VAF 36/121 reads (30%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.997); catalogued as COSV55860634; called by muse, mutect2, varscan2
- OR10C1 | c.559C>T p.Q187* (on ENST00000622521; = p.Q185* on NM_013941.3) | Nonsense Mutation (SNP) | VAF 199/644 reads (31%) | catalogued as rs777826719; called by muse, mutect2, varscan2
- OR2G3 | c.77T>C p.V26A | Missense Mutation (SNP) | VAF 81/350 reads (23%) | SIFT tolerated (0.18); PolyPhen benign (0.006); catalogued as rs751995195, COSV60682804; called by muse, mutect2, varscan2
- OR2T10 | c.824C>A p.S275Y | Missense Mutation (SNP) | VAF 70/304 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as COSV57898000; called by muse, mutect2, varscan2
- OR4M1 | c.814G>A p.V272M | Missense Mutation (SNP) | VAF 63/190 reads (33%) | SIFT tolerated (0.25); PolyPhen benign (0.017); catalogued as COSV60062180; called by muse, mutect2, varscan2
- OR6C75 | c.599dup p.L200Ffs*53 | Frame Shift Ins (INS) | VAF 87/306 reads (28%) | catalogued as rs746200712; called by mutect2, varscan2
- OR7D2 | c.881A>G p.N294S | Missense Mutation (SNP) | VAF 70/175 reads (40%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.931); catalogued as rs776062386, COSV60140984; called by muse, mutect2, varscan2
- PDGFRA | c.2942G>C p.R981P | Missense Mutation (SNP) | VAF 122/340 reads (36%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.862); catalogued as rs368266633, COSV57266911, COSV57270500, COSV57272250; called by muse, varscan2
- PGM2 | c.1096C>T p.R366C | Missense Mutation (SNP) | VAF 20/84 reads (24%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.505); catalogued as rs151106378; called by muse, mutect2, varscan2
- PLBD2 | c.782A>G p.H261R | Missense Mutation (SNP) | VAF 28/462 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs1372718518, COSV55108626; called by muse, mutect2
- PLEC | c.10135C>G p.P3379A (on ENST00000322810 / NM_201380.4; = p.P3269A on NM_000445.5) | Missense Mutation (SNP) | VAF 138/755 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.006); catalogued as COSV59681848; called by muse, mutect2, varscan2
- PNLIPRP3 | c.1234A>T p.N412Y | Missense Mutation (SNP) | VAF 22/43 reads (51%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.95); catalogued as COSV65049407; called by muse, mutect2, varscan2
- POLR1B | c.1613-2A>G p.X538_splice | Splice Site (SNP) | VAF 21/86 reads (24%) | catalogued as COSV54502412; called by muse, mutect2, varscan2
- POLR2A | c.2595C>G p.I865M | Missense Mutation (SNP) | VAF 57/109 reads (52%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.66); catalogued as rs201063777; called by muse, mutect2, varscan2
- PPFIA4 | c.1075C>T p.R359C | Missense Mutation (SNP) | VAF 22/202 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs769833575, COSV55319914; called by muse, varscan2
- PRB4 | c.451C>G p.Q151E | Missense Mutation (SNP) | VAF 35/98 reads (36%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.007); catalogued as COSV54399676, COSV54400481; called by muse, mutect2, varscan2
- PREX2 | c.3716T>A p.F1239Y | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV55794818; called by muse, mutect2, varscan2
- PRM3 | c.308C>A p.S103Y | Missense Mutation (SNP) | VAF 66/184 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.022); catalogued as COSV54113739; called by muse, mutect2, varscan2
- PTK2 | c.1688G>T p.G563V | Missense Mutation (SNP) | VAF 57/192 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV61790686; called by muse, mutect2, varscan2
- RAB22A | c.437A>C p.E146A | Missense Mutation (SNP) | VAF 43/135 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV54833387; called by muse, mutect2, varscan2
- RAB22A | c.438G>T p.E146D | Missense Mutation (SNP) | VAF 42/135 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as COSV54833399; called by muse, mutect2, varscan2
- RELN | c.4154G>T p.R1385I | Missense Mutation (SNP) | VAF 86/338 reads (25%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.958); catalogued as COSV59028270; called by mutect2, varscan2
- ROBO2 | c.1712T>C p.V571A | Missense Mutation (SNP) | VAF 104/330 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.439); catalogued as COSV100167204; called by muse, mutect2, varscan2
- SFXN5 | c.625+1G>A p.X209_splice | Splice Site (SNP) | VAF 32/119 reads (27%) | catalogued as COSV55589755; called by muse, varscan2
- SLC22A11 | c.728C>T p.A243V | Missense Mutation (SNP) | VAF 34/142 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.023); catalogued as rs138399841; called by muse, mutect2, varscan2
- SLCO4C1 | c.2132T>C p.V711A | Missense Mutation (SNP) | VAF 22/38 reads (58%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as COSV60519279; called by muse, mutect2, varscan2
- SLITRK6 | c.2374G>T p.G792* | Nonsense Mutation (SNP) | VAF 92/197 reads (47%) | catalogued as COSV68391355, COSV68391921; called by muse, mutect2, varscan2
- SMG1 | c.4179G>T p.W1393C | Missense Mutation (SNP) | VAF 25/83 reads (30%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.57); catalogued as COSV67174259; called by muse, mutect2, varscan2
- SPECC1L | c.365C>T p.T122I | Missense Mutation (SNP) | VAF 73/231 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.283); catalogued as COSV58660946; called by muse, mutect2, varscan2
- SSTR4 | c.1021G>T p.E341* | Nonsense Mutation (SNP) | VAF 82/284 reads (29%) | catalogued as COSV99658598; called by muse, mutect2
- TAS2R16 | c.682T>G p.S228A | Missense Mutation (SNP) | VAF 107/214 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV50798424; called by muse, mutect2, varscan2
- TCF12 | c.1253C>A p.A418D | Missense Mutation (SNP) | VAF 70/153 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV51018907; called by muse, mutect2, varscan2
- TCHH | c.1772A>G p.K591R | Missense Mutation (SNP) | VAF 52/284 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.01); catalogued as rs776388579, COSV64277187; called by mutect2, varscan2
- TCIRG1 | c.2455A>C p.K819Q | Missense Mutation (SNP) | VAF 168/565 reads (30%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.991); catalogued as COSV55837091; called by muse, mutect2, varscan2
- TDRKH | c.1524G>C p.M508I | Missense Mutation (SNP) | VAF 35/148 reads (24%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as COSV58619198; called by muse, mutect2, varscan2
- TECPR2 | c.1965C>G p.S655R | Missense Mutation (SNP) | VAF 133/470 reads (28%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); catalogued as COSV63973503; called by muse, mutect2, varscan2
- TET1 | c.23G>A p.R8K | Missense Mutation (SNP) | VAF 15/28 reads (54%) | SIFT tolerated (0.49); PolyPhen benign (0.018); catalogued as rs778536892, COSV65388487; called by muse, mutect2, varscan2
- TIGIT | c.394G>C p.A132P | Missense Mutation (SNP) | VAF 70/181 reads (39%) | SIFT tolerated (0.13); PolyPhen benign (0.033); catalogued as COSV67328986, COSV67329359; called by muse, mutect2, varscan2
- TMEM94 | c.2884C>G p.L962V | Missense Mutation (SNP) | VAF 82/271 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV58599104; called by muse, mutect2, varscan2
- TRABD | c.205G>T p.A69S | Missense Mutation (SNP) | VAF 62/294 reads (21%) | SIFT tolerated (0.13); PolyPhen benign (0.081); catalogued as COSV57713937; called by muse, mutect2, varscan2
- TRIM49C | c.979A>C p.S327R | Missense Mutation (SNP) | VAF 80/413 reads (19%) | SIFT tolerated (0.19); PolyPhen benign (0.028); catalogued as COSV71510527, COSV71511634; called by muse, mutect2, varscan2
- TTC3 | c.5229G>C p.E1743D | Missense Mutation (SNP) | VAF 51/168 reads (30%) | SIFT tolerated (0.4); PolyPhen benign (0.023); catalogued as COSV61294843; called by muse, mutect2, varscan2
- TTN | c.97903C>T p.R32635W (on ENST00000591111; = p.R25211W on NM_003319.4) | Missense Mutation (SNP) | VAF 144/505 reads (29%) | PolyPhen probably damaging (0.973); catalogued as rs781432886, COSV60278748; called by muse, mutect2, varscan2
- TTN | c.68568T>A p.Y22856* (on ENST00000591111; = p.Y15432* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 43/138 reads (31%) | catalogued as COSV60278781; called by muse, mutect2, varscan2
- UBE2E1 | c.491C>G p.P164R | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.768); catalogued as COSV60669394; called by muse, mutect2, varscan2
- UBR4 | c.8743A>C p.S2915R | Missense Mutation (SNP) | VAF 24/46 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV64396739; called by muse, mutect2, varscan2
- UCHL5 | c.419A>G p.H140R | Missense Mutation (SNP) | VAF 29/191 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV66486971; called by muse, mutect2, varscan2
- UGT2B15 | c.1274A>G p.D425G | Missense Mutation (SNP) | VAF 30/106 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.627); catalogued as COSV57734543, COSV57736158; called by muse, mutect2, varscan2
- UNC5D | c.730T>A p.S244T | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV54826704; called by muse, mutect2, varscan2
- XIRP1 | c.1683G>A p.M561I | Missense Mutation (SNP) | VAF 184/540 reads (34%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV61140445; called by mutect2, varscan2
- ZFP92 | c.694G>A p.G232S | Missense Mutation (SNP) | VAF 88/196 reads (45%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.604); catalogued as rs782446518, COSV58598984; called by muse, mutect2, varscan2
- ZNF101 | c.476G>A p.R159H | Missense Mutation (SNP) | VAF 38/146 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV58909752; called by muse, mutect2, varscan2
- ZNF318 | c.1853G>A p.R618Q | Missense Mutation (SNP) | VAF 151/288 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1365535140, COSV58936460; called by muse, mutect2, varscan2
- ZNF394 | c.38A>G p.D13G | Missense Mutation (SNP) | VAF 46/80 reads (58%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.001); catalogued as COSV58744230; called by mutect2, varscan2
- ZNF438 | c.250C>T p.Q84* | Nonsense Mutation (SNP) | VAF 74/224 reads (33%) | catalogued as COSV59199682; called by muse, mutect2, varscan2
- ZNF528 | c.273G>C p.E91D | Missense Mutation (SNP) | VAF 18/77 reads (23%) | SIFT tolerated (0.57); PolyPhen benign (0.138); catalogued as COSV64620827; called by muse, mutect2, varscan2
- ZNF81 | c.297G>C p.K99N | Missense Mutation (SNP) | VAF 31/107 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as COSV58578151; called by muse, mutect2, varscan2
- ZNF827 | c.1913G>A p.G638E | Missense Mutation (SNP) | VAF 53/179 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.048); catalogued as COSV101061094, COSV65230818; called by muse, mutect2, varscan2
- ZNRF1 | c.571C>G p.L191V | Missense Mutation (SNP) | VAF 91/305 reads (30%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.856); catalogued as COSV57729507; called by muse, mutect2, varscan2
- ZP2 | c.1621G>C p.V541L | Missense Mutation (SNP) | VAF 30/83 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.394); catalogued as COSV54816155; called by muse, mutect2, varscan2
- ZSCAN32 | c.1156C>G p.Q386E (on ENST00000396846; = p.Q407E on NM_017810.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 90/317 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as COSV59236838, COSV59237067; called by muse, mutect2, varscan2
- ADAMTS2 | c.1835G>A p.R612H | Missense Mutation (SNP) | VAF 136/418 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.357); called by muse, mutect2, varscan2
- ADAMTSL2 | c.2734C>T p.P912S | Missense Mutation (SNP) | VAF 117/239 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.743); called by muse, mutect2, varscan2
- ADGRB1 | c.1957_1962delinsCA p.A653Hfs*37 | Frame Shift Del (DEL) | VAF 55/411 reads (13%) | called by pindel, varscan2*
- ALK | c.3813_3818del p.F1271_M1273delinsL | In Frame Del (DEL) | VAF 40/171 reads (23%) | called by mutect2, pindel, varscan2
- ANKRD20A2P | c.2467A>T p.I823F | Missense Mutation (SNP) | VAF 37/173 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.139); called by muse, mutect2, varscan2
- ARMH1 | c.1023C>A p.S341R | Missense Mutation (SNP) | VAF 52/118 reads (44%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- C17orf99 | c.352_370+3del p.X118_splice | Splice Site (DEL) | VAF 50/292 reads (17%) | called by mutect2, pindel, varscan2
- CFAP74 | c.3814C>T p.P1272S | Missense Mutation (SNP) | VAF 159/422 reads (38%) | SIFT tolerated (0.22); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- CYHR1 | c.818G>A p.R273H | Missense Mutation (SNP) | VAF 21/718 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.818); called by muse, mutect2
- DSCAML1 | c.5370_5387del p.R1791_S1796del (on ENST00000321322; = p.R1731_S1736del on NM_020693.4) | In Frame Del (DEL) | VAF 21/82 reads (26%) | called by mutect2, varscan2
- EVC2 | c.3552G>C p.R1184S | Missense Mutation (SNP) | VAF 20/196 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.053); called by muse, mutect2
- FAM102A | c.939_964del p.E313Dfs*61 (on ENST00000373095 / NM_001035254.3; = p.E171Dfs*61 on NM_203305.2) | Frame Shift Del (DEL) | VAF 72/288 reads (25%) | called by mutect2, pindel, varscan2
- FRMPD3 | c.715C>T p.L239F | Missense Mutation (SNP) | VAF 48/112 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- GAN | c.1769T>A p.F590Y | Missense Mutation (SNP) | VAF 45/317 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- GAR1 | c.467_474del p.R156Tfs*6 | Frame Shift Del (DEL) | VAF 13/63 reads (21%) | called by pindel*, varscan2
- HSPG2 | c.2087C>G p.T696S | Missense Mutation (SNP) | VAF 335/619 reads (54%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.76); called by muse, mutect2, varscan2
- IL17RE | c.170G>A p.C57Y | Missense Mutation (SNP) | VAF 16/196 reads (8%) | SIFT tolerated, low confidence (0.81); PolyPhen benign (0.054); called by muse, mutect2
- ISLR | c.647T>A p.L216H | Missense Mutation (SNP) | VAF 223/346 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- KIAA2012 | c.2133G>C p.R711S | Missense Mutation (SNP) | VAF 44/93 reads (47%) | SIFT deleterious (0.01); called by muse, mutect2, varscan2
- KIAA2012 | c.2305C>G p.L769V | Missense Mutation (SNP) | VAF 67/210 reads (32%) | SIFT tolerated (0.1); called by muse, mutect2, varscan2
- MIS18BP1 | c.2655_2664del p.L885Ffs*19 | Frame Shift Del (DEL) | VAF 12/35 reads (34%) | called by mutect2, pindel, varscan2
- MYRF | c.2159G>C p.S720T (on ENST00000278836 / NM_001127392.3; = p.S711T on NM_013279.4) | Missense Mutation (SNP) | VAF 65/171 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.223); called by muse, mutect2, varscan2
- NACC1 | c.729_743del p.G244_A248del | In Frame Del (DEL) | VAF 186/382 reads (49%) | called by mutect2, varscan2
- NUP98 | c.1677_1683del p.R559Sfs*26 | Frame Shift Del (DEL) | VAF 6/43 reads (14%) | called by mutect2, pindel, varscan2
- PCDHGB3 | c.1937T>C p.V646A | Missense Mutation (SNP) | VAF 23/708 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); called by muse, mutect2
- PELO | c.119G>T p.R40L | Missense Mutation (SNP) | VAF 89/252 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.099); called by muse, mutect2, varscan2
- PLCL2 | c.3219_3231del p.L1074Rfs*8 (on ENST00000615277 / NM_001144382.2; = p.L948Rfs*8 on NM_015184.5) | Frame Shift Del (DEL) | VAF 22/59 reads (37%) | called by mutect2, pindel, varscan2
- PROSER2 | c.1173_1216del p.A392Hfs*86 | Frame Shift Del (DEL) | VAF 12/142 reads (8%) | called by mutect2, pindel
- RWDD1 | c.160_163del p.F54Hfs*21 | Frame Shift Del (DEL) | VAF 25/103 reads (24%) | called by mutect2, pindel, varscan2
- SALL3 | c.1339C>A p.P447T | Missense Mutation (SNP) | VAF 93/234 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by mutect2, varscan2
- SLC27A3 | c.260_305del p.R87Pfs*2 | Frame Shift Del (DEL) | VAF 76/342 reads (22%) | called by mutect2, pindel
- TSPAN18 | c.684_685del p.V229Tfs*25 | Frame Shift Del (DEL) | VAF 72/324 reads (22%) | called by mutect2, pindel, varscan2
- TTN | c.64823_64828del p.V21608_T21609del (on ENST00000591111; = p.V14184_T14185del on NM_003319.4) | In Frame Del (DEL) | VAF 6/22 reads (27%) | called by mutect2, varscan2
- UBTF | c.1614_1626+21del p.X538_splice | Splice Site (DEL) | VAF 55/202 reads (27%) | called by mutect2, pindel, varscan2
- UMODL1 | c.20T>C p.L7P | Missense Mutation (SNP) | VAF 20/82 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- WDR11 | c.1998_2008del p.L669Hfs*13 | Frame Shift Del (DEL) | VAF 62/107 reads (58%) | called by mutect2, pindel, varscan2
- WNT9A | c.822_865del p.S275Gfs*5 | Frame Shift Del (DEL) | VAF 196/874 reads (22%) | called by mutect2, pindel
- ZGRF1 | c.4635_4656del p.K1546Ifs*7 | Frame Shift Del (DEL) | VAF 10/110 reads (9%) | called by mutect2, varscan2
- ZGRF1 | c.1998T>G p.I666M | Missense Mutation (SNP) | VAF 7/139 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.315); called by muse, mutect2
- ZNF708 | c.497dup p.N166Kfs*6 | Frame Shift Ins (INS) | VAF 61/218 reads (28%) | called by mutect2, pindel, varscan2
- ABHD11 | c.591T>A p.R197= | Silent (SNP) | VAF 196/636 reads (31%) | catalogued as COSV56106346; called by muse, mutect2, varscan2
- ADAMTS2 | c.1044C>T p.L348= | Silent (SNP) | VAF 132/445 reads (30%) | catalogued as COSV51097357; called by muse, mutect2, varscan2
- AGRN | c.339G>A p.R113= | Silent (SNP) | VAF 130/447 reads (29%) | catalogued as COSV101038899; called by muse, mutect2, varscan2
- AHCYL2 | c.219C>G p.L73= | Silent (SNP) | VAF 18/65 reads (28%) | called by muse, mutect2, varscan2
- ANKRD30B | c.1509T>C p.T503= | Silent (SNP) | VAF 13/38 reads (34%) | catalogued as COSV62821725; called by muse, mutect2, varscan2
- ASS1 | c.198G>A p.R66= | Silent (SNP) | VAF 35/529 reads (7%) | catalogued as rs747885215, COSV61690687; called by muse, mutect2
- ATP8B2 | c.18T>G p.A6= | Silent (SNP) | VAF 80/274 reads (29%) | catalogued as COSV59248237; called by muse, mutect2, varscan2
- CC2D2A | c.1977C>T p.S659= | Silent (SNP) | VAF 13/39 reads (33%) | catalogued as COSV101052792; called by muse, mutect2
- CDKN1C | c.909C>T p.G303= | Silent (SNP) | VAF 46/136 reads (34%) | catalogued as rs377216794; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CEACAM16 | c.609G>A p.V203= | Silent (SNP) | VAF 57/163 reads (35%) | called by muse, mutect2, varscan2
- CLIP1 | c.3154C>T p.L1052= (on ENST00000620786 / NM_001247997.1; = p.L1041= on NM_002956.2) | Silent (SNP) | VAF 136/231 reads (59%) | catalogued as rs771766351, COSV56807265; called by muse, mutect2, varscan2
- CNGA4 | c.1179G>T p.L393= | Silent (SNP) | VAF 129/362 reads (36%) | catalogued as COSV66006828; called by muse, varscan2
- CPSF2 | c.2325A>G p.L775= | Silent (SNP) | VAF 13/35 reads (37%) | catalogued as rs765674847, COSV54100328; called by muse, mutect2, varscan2
- DEAF1 | c.1539C>T p.S513= | Silent (SNP) | VAF 101/354 reads (29%) | catalogued as rs1379218706, COSV58608956; called by mutect2, varscan2
- DNAH11 | c.4425C>T p.Y1475= | Silent (SNP) | VAF 23/37 reads (62%) | catalogued as rs373706559; called by muse, mutect2, varscan2
- EEF1D | c.6T>A p.A2= | Silent (SNP) | VAF 45/263 reads (17%) | catalogued as COSV57822165; called by muse, mutect2, varscan2
- FAM83C | c.471C>T p.N157= | Silent (SNP) | VAF 123/399 reads (31%) | catalogued as rs1269412702; called by muse, mutect2, varscan2
- GP5 | c.585G>A p.K195= | Silent (SNP) | VAF 91/260 reads (35%) | catalogued as rs1316295276, COSV55468664; called by muse, mutect2, varscan2
- H2BC4 | c.138G>C p.L46= | Silent (SNP) | VAF 94/293 reads (32%) | catalogued as COSV58417398; called by muse, mutect2, varscan2
- IGHV2-26 | c.177T>C p.R59= | Silent (SNP) | VAF 131/569 reads (23%) | catalogued as rs1555476580; called by muse, varscan2
- KIAA0895L | c.1077C>A p.R359= | Silent (SNP) | VAF 69/223 reads (31%) | called by muse, mutect2, varscan2
- KRTAP20-3 | c.36C>A p.G12= | Silent (SNP) | VAF 58/179 reads (32%) | catalogued as COSV66999907; called by muse, mutect2, varscan2
- LRP1 | c.13285C>T p.L4429= | Silent (SNP) | VAF 57/194 reads (29%) | catalogued as rs374728435; called by mutect2, varscan2
- MADD | c.279C>A p.I93= | Silent (SNP) | VAF 139/338 reads (41%) | catalogued as COSV60628847; called by muse, mutect2, varscan2
- MAP3K2 | c.501A>T p.P167= | Silent (SNP) | VAF 23/41 reads (56%) | catalogued as COSV61295785; called by muse, mutect2, varscan2
- MAPK6 | c.1272T>C p.C424= | Silent (SNP) | VAF 27/58 reads (47%) | catalogued as COSV55931318; called by muse, mutect2, varscan2
- MATN4 | c.465C>T p.A155= | Silent (SNP) | VAF 32/87 reads (37%) | catalogued as rs1308870453, COSV59212870; called by muse, mutect2, varscan2
- MX1 | c.1560G>A p.L520= | Silent (SNP) | VAF 33/102 reads (32%) | catalogued as COSV55820598; called by muse, mutect2, varscan2
- MYCBP2 | c.5001G>A p.A1667= (on ENST00000357337; = p.A1705= on NM_015057.5) | Silent (SNP) | VAF 17/53 reads (32%) | catalogued as rs377188860; called by muse, mutect2, varscan2
- OR2T34 | c.288C>A p.T96= | Silent (SNP) | VAF 134/842 reads (16%) | catalogued as COSV60901692; called by muse, mutect2, varscan2
- P2RX1 | c.207C>G p.L69= | Silent (SNP) | VAF 10/242 reads (4%) | called by muse, mutect2
- PCDHB16 | c.702C>T p.D234= | Silent (SNP) | VAF 98/288 reads (34%) | catalogued as COSV53369152; called by muse, mutect2, varscan2
- PGLYRP4 | c.760C>T p.L254= | Silent (SNP) | VAF 115/553 reads (21%) | catalogued as COSV62836120; called by muse, mutect2, varscan2
- PMEL | c.1083T>C p.T361= | Silent (SNP) | VAF 125/441 reads (28%) | catalogued as COSV59388190; called by muse, mutect2, varscan2
- RSPO1 | c.654C>A p.G218= | Silent (SNP) | VAF 235/688 reads (34%) | catalogued as COSV62975127; called by muse, mutect2, varscan2
- SFMBT2 | c.801A>G p.E267= | Silent (SNP) | VAF 84/170 reads (49%) | catalogued as COSV62815104; called by muse, mutect2, varscan2
- SLC39A4 | c.1239C>T p.F413= (on ENST00000301305 / NM_001374839.1; = p.F388= on NM_017767.3) | Silent (SNP) | VAF 325/1080 reads (30%) | called by muse, mutect2, varscan2
- SP4 | c.2340C>T p.N780= | Silent (SNP) | VAF 29/116 reads (25%) | catalogued as COSV56025802; called by muse, mutect2, varscan2
- SPTBN4 | c.4686G>C p.R1562= | Silent (SNP) | VAF 7/27 reads (26%) | called by muse, mutect2, varscan2
- STAT3 | c.2187C>T p.R729= (on ENST00000264657 / NM_001369512.1; = p.R728= on NM_003150.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 40/134 reads (30%) | catalogued as COSV52892113; called by muse, mutect2, varscan2
- UMODL1 | c.21G>T p.L7= | Silent (SNP) | VAF 18/86 reads (21%) | called by muse, varscan2
- USP31 | c.459C>G p.A153= | Silent (SNP) | VAF 12/39 reads (31%) | catalogued as COSV54850884, COSV54852733; called by muse, mutect2, varscan2
- ZNF517 | c.1368C>A p.A456= | Silent (SNP) | VAF 86/170 reads (51%) | called by muse, mutect2, varscan2
- ZSWIM9 | c.867G>T p.V289= | Silent (SNP) | VAF 12/20 reads (60%) | called by muse, varscan2
- AC125421.1 | n.325-181G>A | Intron (SNP) | VAF 92/455 reads (20%) | called by muse, mutect2, varscan2
- ARHGAP28 | c.544-178_544-177del | Intron (DEL) | VAF 22/101 reads (22%) | called by mutect2, pindel, varscan2
- ASCC2 | c.541+395_541+405del | Intron (DEL) | VAF 9/39 reads (23%) | called by mutect2, pindel, varscan2
- CD207 | c.-6C>T | 5'UTR (SNP) | VAF 76/240 reads (32%) | catalogued as COSV101338565; called by muse, mutect2, varscan2
- EFNA5 | c.-16C>A | 5'UTR (SNP) | VAF 12/32 reads (38%) | catalogued as COSV100321428; called by muse, varscan2
- KHSRP | chr19:6411752 T>C | 3'Flank (SNP) | VAF 67/144 reads (47%) | called by muse, mutect2, varscan2
- KIF5A | c.3021-10C>T | Intron (SNP) | VAF 78/224 reads (35%) | catalogued as rs774933373; called by muse, mutect2, varscan2
- MGRN1 | c.*2531C>T | 3'UTR (SNP) | VAF 72/223 reads (32%) | catalogued as rs376895162; called by muse, mutect2, varscan2
- NAP1L6P | n.334G>T | RNA (SNP) | VAF 112/228 reads (49%) | called by muse, mutect2, varscan2
- NAP1L6P | n.333G>T | RNA (SNP) | VAF 112/227 reads (49%) | called by muse, mutect2, varscan2
- NHLRC1 | c.-11C>T | 5'UTR (SNP) | VAF 88/344 reads (26%) | catalogued as rs986435787; called by muse, mutect2, varscan2
- NTNG1 | c.1088-9623T>C | Intron (SNP) | VAF 40/127 reads (31%) | catalogued as COSV64277757; called by muse, mutect2, varscan2
- OR5AK4P | n.547C>G | RNA (SNP) | VAF 157/433 reads (36%) | called by muse, mutect2, varscan2
- OR9Q1 | c.-15+53400G>A | Intron (SNP) | VAF 112/343 reads (33%) | called by muse, mutect2, varscan2
- RASAL1 | c.2101+873G>C | Intron (SNP) | VAF 29/74 reads (39%) | called by muse, mutect2, varscan2
- SLC16A6P1 | n.479C>T | RNA (SNP) | VAF 113/474 reads (24%) | called by muse, mutect2, varscan2
- TAAR3P | n.853C>G | RNA (SNP) | VAF 65/228 reads (29%) | called by muse, mutect2, varscan2
- TGM2 | c.859+97del | Intron (DEL) | VAF 80/291 reads (27%) | catalogued as rs1568691949; called by mutect2, pindel, varscan2
- TIAM2 | c.3168+5755T>C | Intron (SNP) | VAF 33/63 reads (52%) | called by muse, mutect2, varscan2
- TROAP | c.2098+38G>C | Intron (SNP) | VAF 149/402 reads (37%) | catalogued as COSV99226863; called by muse, mutect2, varscan2
- UGT1A7 | c.855+7746C>G | Intron (SNP) | VAF 29/120 reads (24%) | called by muse, mutect2, varscan2
